Somatic mutation profile of tumor specimen ALCH-B36V-TTP1-A (aliquot ALCH-B36V-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B36V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.2 years (23,459 days).
Specimen ALCH-B36V-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 568ed91c-753b-4143-81ea-eb95d4cc8fa2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B36V-NB1-A (Blood Derived Normal), aliquot ALCH-B36V-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8068ce22-a8b8-4244-8468-f92050ff80e1

The open-access MAF lists 447 somatic variants for this specimen: 294 protein-altering or splice-affecting, 84 silent, 69 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 257, Silent 84, Intron 27, Nonsense Mutation 18, RNA 16, 5'UTR 11, 3'UTR 10, Frame Shift Del 7, Splice Region 5, Splice Site 3, 5'Flank 3, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 78/303 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RPS6KA4 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs746466314, COSV53702062; called by muse, mutect2, varscan2
- TP53 | c.216del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 24/167 reads (14%) | catalogued as rs730882018; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- AADACL3 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs567249050; called by muse, mutect2
- ABCD2 | c.1353C>A p.S451R | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as rs762845047, COSV58052539; called by muse, mutect2, varscan2
- ADAMTS5 | c.1607C>G p.A536G | Missense Mutation (SNP) | VAF 46/368 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV53183225; called by muse, varscan2
- ADD2 | c.338C>A p.T113K | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV52459422; called by muse, mutect2, varscan2
- ADGRE1 | c.1606C>G p.L536V | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV99165328; called by muse, mutect2, varscan2
- ADGRG1 | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 15/371 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as rs1337548203; called by muse, mutect2
- AGXT2 | c.1168A>T p.I390F | Missense Mutation (SNP) | VAF 46/540 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs1429497713; called by muse, mutect2
- AK7 | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 13/271 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs1436508483; called by muse, mutect2
- AKAP11 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.357); catalogued as rs764066282; called by muse, mutect2
- ALPK3 | c.4861G>A p.G1621R | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV51931975; called by muse, mutect2
- ARHGAP42 | c.2176G>T p.G726W | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100082641; called by muse, mutect2, varscan2
- ARMC4 | c.1644C>A p.H548Q | Missense Mutation (SNP) | VAF 77/469 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs759708377; called by muse, mutect2, varscan2
- AXIN2 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 35/419 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs1060502160, COSV61057322; ClinVar: uncertain significance; called by muse, mutect2
- C3 | c.3242A>T p.Y1081F | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.747); catalogued as rs531259592; called by muse, mutect2, varscan2
- CCT8L2 | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 60/296 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV63462427; called by muse, mutect2, varscan2
- CDH10 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 125/454 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs777678940, COSV52592692; called by muse, mutect2, varscan2
- CHRDL2 | c.775T>A p.Y259N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330717605; called by muse, mutect2, varscan2
- CLEC4C | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.116); catalogued as COSV63582734; called by muse, mutect2, varscan2
- CLNK | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs533124568; called by muse, mutect2, varscan2
- CPO | c.739G>T p.G247C | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55940433; called by muse, mutect2, varscan2
- CPS1 | c.2590C>A p.L864I | Missense Mutation (SNP) | VAF 44/498 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV51800595; called by muse, mutect2
- DCAF8 | c.43G>C p.A15P | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV100470118; called by muse, mutect2
- DCSTAMP | c.585C>A p.S195R | Missense Mutation (SNP) | VAF 78/382 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV99886053, COSV99886505; called by muse, mutect2, varscan2
- DLGAP3 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52398259; called by muse, mutect2, varscan2
- DNAH5 | c.11800C>T p.P3934S | Missense Mutation (SNP) | VAF 13/279 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV99448342; called by muse, mutect2
- DNAH5 | c.6077G>T p.G2026V | Missense Mutation (SNP) | VAF 50/534 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54237847; called by muse, mutect2
- DST | c.8152G>A p.E2718K | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as COSV55047099; called by muse, mutect2
- DUXB | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 25/309 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs951910970; called by muse, mutect2
- EML1 | c.1963G>T p.V655F | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV51755374; called by muse, mutect2
- EP400 | c.8735C>T p.P2912L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV57778371; called by muse, mutect2, varscan2
- EPHA3 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs1161663372, COSV60702171; called by muse, mutect2, varscan2
- FANCI | c.3116A>G p.Y1039C (on ENST00000310775 / NM_001376911.1; = p.Y979C on NM_018193.3) | Missense Mutation (SNP) | VAF 30/508 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs138702591; called by muse, mutect2
- FNDC3A | c.1842G>A p.M614I (on ENST00000492622 / NM_001079673.2; = p.M558I on NM_014923.5) | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV101256929; called by muse, mutect2
- GABRA1 | c.1239T>A p.F413L | Missense Mutation (SNP) | VAF 57/351 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.338); catalogued as COSV99196297; called by muse, mutect2, varscan2
- GALNT14 | c.1278G>C p.Q426H | Missense Mutation (SNP) | VAF 18/365 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV100205338; called by muse, mutect2
- GALNT7 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 108/420 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.057); catalogued as COSV99397768; called by muse, mutect2, varscan2
- GGA2 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs1299565146; called by muse, mutect2
- GIPC2 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV100883186; called by muse, mutect2
- GOLGB1 | c.2475G>T p.Q825H | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as rs1432976791; called by muse, mutect2, varscan2
- GPLD1 | c.435G>T p.M145I | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as rs1212418621; called by muse, mutect2, varscan2
- HFM1 | c.1574C>G p.S525C | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54026657; called by muse, mutect2
- IGKV1D-33 | c.171G>T p.W57C | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs777212820, COSV101134068; called by muse, mutect2, varscan2
- IRAK3 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104370792; called by muse, mutect2, varscan2
- ISLR2 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs1304784130, COSV62304266; called by muse, mutect2
- ISM2 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53634284; called by muse, mutect2, varscan2
- KCNH2 | c.1174G>T p.A392S | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as COSV100059256; called by muse, mutect2
- KCTD3 | c.1737T>A p.S579R | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs760426861; called by muse, mutect2, varscan2
- KEL | c.2183G>T p.R728L | Missense Mutation (SNP) | VAF 52/310 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.735); catalogued as rs201835469, COSV62333771, COSV62334208; called by muse, mutect2, varscan2
- KIF2B | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 32/404 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52130550; called by muse, mutect2
- LAMA4 | c.4346G>T p.R1449L (on ENST00000230538 / NM_001105206.3; = p.R1442L on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100039885, COSV57906158; called by muse, mutect2, varscan2
- LAMC3 | c.2618C>T p.S873L | Missense Mutation (SNP) | VAF 64/344 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs150207220; called by muse, mutect2, varscan2
- LARGE1 | c.1432G>T p.A478S | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); catalogued as COSV61665342; called by muse, mutect2, varscan2
- LARP4 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs1212210601; called by muse, mutect2, varscan2
- LIPG | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 49/208 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as rs1349265030; called by muse, mutect2, varscan2
- LMF2 | c.1849A>G p.S617G | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs778065919; called by muse, mutect2, varscan2
- MAGEB6 | c.602C>A p.T201K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV66871774, COSV66872105; called by muse, mutect2, varscan2
- MARK1 | c.2115T>G p.S705R | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65071638; called by muse, mutect2
- MED12L | c.6362G>T p.R2121L | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV56378084; called by muse, varscan2
- MLXIPL | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 11/265 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57670357; called by muse, mutect2
- MMP8 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 26/162 reads (16%) | catalogued as rs1322731713; called by muse, mutect2, varscan2
- MROH5 | c.921G>C p.R307S | Missense Mutation (SNP) | VAF 7/164 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV101435952; called by muse, mutect2
- MYBL2 | c.1415C>T p.S472L | Missense Mutation (SNP) | VAF 17/293 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53829238; called by muse, mutect2
- NCAM1 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.836); catalogued as COSV57523107; called by muse, mutect2, varscan2
- NEFM | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.369); catalogued as COSV99647284; called by muse, mutect2
- NRXN3 | c.1981G>T p.G661C (on ENST00000335750 / NM_001330195.2; = p.G288C on NM_004796.6) | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59778101, COSV59781225; called by muse, mutect2, varscan2
- OCLN | c.803G>C p.R268P | Missense Mutation (SNP) | VAF 15/315 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62285701; called by muse, mutect2
- OGDH | c.2915G>C p.R972T | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56056019; called by muse, mutect2
- OR2T2 | c.285C>A p.F95L | Missense Mutation (SNP) | VAF 80/1316 reads (6%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.978); catalogued as COSV61618100; called by muse, mutect2
- OR5W2 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60616895; called by muse, mutect2
- OR6P1 | c.310T>G p.F104V | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100583471; called by muse, mutect2
- OXNAD1 | c.725G>A p.S242N | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.473); catalogued as rs772740883, COSV53266530; called by muse, mutect2, varscan2
- PAPPA2 | c.1617C>A p.N539K | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV62774134; called by muse, mutect2
- PDCD11 | c.1073G>T p.R358L | Missense Mutation (SNP) | VAF 41/464 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV63933407; called by muse, mutect2
- PLXNA2 | c.3691G>C p.D1231H | Missense Mutation (SNP) | VAF 13/288 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100885525; called by muse, mutect2
- POM121 | c.3527G>C p.G1176A (on ENST00000434423; = p.G911A on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1159191999; called by muse, mutect2, varscan2
- PRAG1 | c.2870del p.G957Dfs*11 | Frame Shift Del (DEL) | VAF 8/90 reads (9%) | catalogued as rs766379432; called by mutect2, pindel
- PRKCZ | c.775G>C p.G259R | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101058015; called by muse, mutect2
- PSG5 | c.388A>T p.R130W | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV61654697; called by muse, mutect2, varscan2
- RAPGEF2 | c.487C>G p.P163A | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.383); catalogued as rs962931388; called by muse, mutect2
- RARRES2 | c.356T>C p.I119T | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs916393928; called by muse, mutect2
- RILP | c.173T>C p.V58A | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs778413813; called by muse, mutect2, varscan2
- ROBO3 | c.1739C>A p.P580Q | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV67301399; called by muse, mutect2, varscan2
- SERPINB4 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 43/292 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.109); catalogued as rs772083334; called by muse, mutect2, varscan2
- SLC13A5 | c.676G>T p.G226W | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53422649, COSV53424679; called by muse, mutect2, varscan2
- SLC24A5 | c.433T>C p.S145P | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1333249603; called by muse, mutect2, varscan2
- SLC6A2 | c.1510G>C p.D504H | Missense Mutation (SNP) | VAF 29/438 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54916686; called by muse, mutect2
- SLC7A6 | c.620T>G p.I207S | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54720509; called by muse, mutect2
- SPAST | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as rs1553394603, CM030280, CM051993, COSV100188301; called by muse, mutect2
- SRPX | c.296C>A p.S99Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV100656342, COSV59437891; called by muse, mutect2
- SULT1B1 | c.785C>A p.A262D | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs748523149; called by muse, mutect2, varscan2
- TEK | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 13/415 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV66231598; called by muse, mutect2
- TENM2 | c.990C>G p.F330L (on ENST00000518659 / NM_001122679.2; = p.F139L on NM_001080428.3) | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as COSV101319099; called by muse, mutect2, varscan2
- THSD7B | c.1835C>G p.S612C | Missense Mutation (SNP) | VAF 13/296 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV99067258; called by muse, mutect2
- TICRR | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 79/348 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1203305713, COSV99175976; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1648A>C p.N550H | Missense Mutation (SNP) | VAF 82/290 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1035282388; called by muse, mutect2, varscan2
- TRHDE | c.1501G>T p.G501C | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53855609, COSV53870277; called by muse, mutect2, varscan2
- TRPV6 | c.176T>C p.F59S | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs200004493; called by muse, mutect2
- USF3 | c.3686C>G p.S1229* | Nonsense Mutation (SNP) | VAF 12/219 reads (5%) | catalogued as COSV100325582; called by muse, mutect2
- VAV1 | c.1511C>A p.S504Y | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58387261; called by muse, mutect2, varscan2
- VPS13D | c.11114G>T p.R3705L | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.109); catalogued as COSV50643532; called by muse, mutect2, varscan2
- WT1 | c.1293G>T p.R431S | Missense Mutation (SNP) | VAF 65/527 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.626); catalogued as COSV60068010, COSV60071892; called by muse, mutect2, varscan2
- XRCC2 | c.72G>C p.L24F | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63770313; called by muse, mutect2
- YRDC | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.338); catalogued as COSV65990090; called by muse, mutect2, varscan2
- ZNF132 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs1378612965; called by muse, mutect2
- ZNF440 | c.1135C>G p.H379D | Missense Mutation (SNP) | VAF 24/379 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV58372460; called by muse, mutect2
- AASDH | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 22/437 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ABCA1 | c.1715G>A p.G572E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- ABCF3 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2
- ADAMTS14 | c.2567G>T p.W856L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2135G>T p.W712L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRG1 | c.1935C>G p.I645M | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- AHNAK2 | c.5252T>C p.M1751T | Missense Mutation (SNP) | VAF 42/280 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- AICDA | c.485G>T p.W162L | Missense Mutation (SNP) | VAF 57/322 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AICDA | c.484T>C p.W162R | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AJUBA | c.788C>A p.S263Y | Missense Mutation (SNP) | VAF 20/423 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2
- AMER3 | c.1393G>T p.G465W | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ANKRD20A1 | c.901G>T p.V301F | Missense Mutation (SNP) | VAF 56/583 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ANO5 | c.472A>C p.I158L | Missense Mutation (SNP) | VAF 44/382 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.02); called by muse, mutect2
- AP2M1 | c.1074G>A p.M358I | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- AP3S2 | c.69C>T p.F23= | Splice Region (SNP) | VAF 13/180 reads (7%) | called by muse, mutect2
- ARHGAP21 | c.5283G>T p.W1761C | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGEF28 | c.1382G>T p.G461V | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ARHGEF6 | c.590G>T p.W197L | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARL14EP | c.117G>T p.M39I | Missense Mutation (SNP) | VAF 25/293 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- ARL14EPL | c.91C>A p.Q31K | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ASAP2 | c.1525G>C p.D509H | Missense Mutation (SNP) | VAF 11/338 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); called by muse, mutect2
- BPI | c.854T>C p.V285A (on ENST00000262865; = p.V281A on NM_001725.3) | Missense Mutation (SNP) | VAF 13/308 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- BTBD9 | c.1580C>G p.T527S | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.899); called by muse, mutect2
- C9orf72 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CACNA1G | c.1917G>C p.Q639H | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CAPZA2 | c.749T>A p.M250K | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- CARMIL3 | c.3002A>G p.Q1001R | Missense Mutation (SNP) | VAF 235/457 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CAVIN4 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 56/324 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CBFA2T2 | c.871C>T p.L291F | Missense Mutation (SNP) | VAF 15/343 reads (4%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.994); called by muse, mutect2
- CCDC92 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 14/250 reads (6%) | called by muse, mutect2
- CDH11 | c.746C>G p.S249* | Nonsense Mutation (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- CFAP46 | c.3855G>T p.E1285D | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CHAF1A | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CHD1 | c.463G>T p.G155* | Nonsense Mutation (SNP) | VAF 25/119 reads (21%) | called by muse, mutect2, varscan2
- CMKLR1 | c.58G>C p.D20H (on ENST00000312143 / NM_001142344.2; = p.D18H on NM_004072.3) | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2
- CNBD1 | c.160C>A p.R54= | Splice Region (SNP) | VAF 14/90 reads (16%) | called by muse, varscan2
- CNGB3 | c.409A>T p.K137* | Nonsense Mutation (SNP) | VAF 121/666 reads (18%) | called by muse, mutect2, varscan2
- COQ8A | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 22/432 reads (5%) | called by muse, mutect2
- CSMD1 | c.9490G>T p.E3164* (on ENST00000520002; = p.E3163* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 25/122 reads (20%) | called by muse, mutect2, varscan2
- CSMD3 | c.6224C>A p.S2075Y (on ENST00000297405 / NM_001363185.1; = p.S1971Y on NM_052900.3) | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- CST4 | c.368A>T p.Y123F | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CTAGE15 | c.1270A>G p.S424G | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CYP4F22 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 21/480 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- DCAF12L1 | c.860A>T p.H287L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DIS3L | c.1663G>C p.D555H (on ENST00000319212 / NM_001143688.3; = p.D472H on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- DR1 | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); called by muse, mutect2
- EIF4A2 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 23/333 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.024); called by muse, mutect2
- EPN2 | c.1429C>G p.L477V | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2
- ERBB4 | c.1815C>A p.F605L | Missense Mutation (SNP) | VAF 75/619 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ETAA1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 7/199 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM122A | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 21/342 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.118); called by muse, mutect2
- FAM124B | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM83B | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); called by muse, mutect2
- FAM83D | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 57/384 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- FAT1 | c.2587A>T p.T863S | Missense Mutation (SNP) | VAF 11/245 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.208); called by muse, mutect2
- FBXL13 | c.676T>A p.L226M | Missense Mutation (SNP) | VAF 79/366 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FHDC1 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FUT7 | c.254T>A p.L85Q | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GABRG2 | c.825G>C p.W275C (on ENST00000361925 / NM_001375343.1; = p.W235C on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/405 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GARNL3 | c.275C>G p.P92R | Missense Mutation (SNP) | VAF 35/500 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GIMAP8 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLI1 | c.950A>G p.N317S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- GXYLT2 | c.535G>T p.V179F | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.102); called by muse, mutect2
- HEPHL1 | c.2014C>A p.H672N | Missense Mutation (SNP) | VAF 56/427 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HIVEP2 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.021); called by muse, mutect2
- ICAM1 | c.47_65del p.L16Qfs*25 | Frame Shift Del (DEL) | VAF 22/101 reads (22%) | called by mutect2, pindel
- IGKV2D-26 | c.278G>C p.G93A | Missense Mutation (SNP) | VAF 54/299 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ISLR2 | c.321C>A p.S107R | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITGA4 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.018); called by muse, mutect2
- JUN | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNJ2 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2
- KDR | c.3970G>A p.A1324T | Missense Mutation (SNP) | VAF 87/341 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KLK6 | c.39A>G p.A13= | Splice Region (SNP) | VAF 30/318 reads (9%) | called by muse, mutect2
- KRBA2 | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- KRTAP19-1 | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 32/635 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2
- MADD | c.117dup p.E41Gfs*5 | Frame Shift Ins (INS) | VAF 12/127 reads (9%) | called by mutect2, pindel
- MAGEH1 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP1LC3C | c.425G>T p.R142I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); called by muse, mutect2
- MAP3K2 | c.1799A>T p.E600V | Missense Mutation (SNP) | VAF 61/340 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- MAVS | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- MCF2L2 | c.2918G>T p.S973I | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- MKKS | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 13/239 reads (5%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.677); called by muse, mutect2
- MLF1 | c.281dup p.X94_splice | Splice Site (INS) | VAF 19/165 reads (12%) | called by mutect2, pindel, varscan2
- MUC19 | c.1373-1G>T p.X458_splice | Splice Site (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- MYH15 | c.3073G>C p.E1025Q | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- MYO9A | c.6963C>G p.I2321M | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MYT1 | c.2879G>T p.S960I | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); called by muse, mutect2
- NAPSA | c.580C>G p.L194V | Missense Mutation (SNP) | VAF 16/281 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NRXN3 | c.1655C>G p.S552* (on ENST00000557594 / NM_001272020.2; = p.S976* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- NUCKS1 | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 99/354 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- OLFM4 | c.844C>G p.H282D | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR10Q1 | c.746A>C p.H249P | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OR14I1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- OR2L2 | c.773A>T p.Y258F | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- OR2L8 | c.802A>T p.T268S | Missense Mutation (SNP) | VAF 24/456 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.068); called by muse, mutect2
- OR2M7 | c.62G>T p.S21I | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); called by muse, mutect2
- OR3A3 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- OR5K2 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 60/310 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- OSBPL3 | c.546del p.K183Sfs*52 | Frame Shift Del (DEL) | VAF 16/132 reads (12%) | called by mutect2, pindel
- OVCH1 | c.2774G>T p.R925I | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- PACRG | c.350G>T p.C117F | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- PCDH17 | c.3334A>T p.S1112C | Missense Mutation (SNP) | VAF 79/373 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- PCDH17 | c.3335G>T p.S1112I | Missense Mutation (SNP) | VAF 78/373 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PCDHB4 | c.619T>G p.F207V | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCED1B | c.479dup p.V161Gfs*46 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- PCF11 | c.3514G>T p.G1172C | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2
- PCMTD1 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 12/315 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2
- PCNX1 | c.5700del p.S1901Vfs*34 | Frame Shift Del (DEL) | VAF 54/414 reads (13%) | called by mutect2, pindel, varscan2
- PDIA3 | c.697A>T p.K233* | Nonsense Mutation (SNP) | VAF 30/121 reads (25%) | called by muse, mutect2, varscan2
- PEX1 | c.139A>T p.I47L | Missense Mutation (SNP) | VAF 59/300 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PIEZO2 | c.1616A>G p.Y539C | Missense Mutation (SNP) | VAF 63/406 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PIK3C2G | c.3653C>A p.A1218E (on ENST00000676171; = p.A1177E on NM_004570.5) | Missense Mutation (SNP) | VAF 75/293 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PITX3 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PIWIL1 | c.1200T>A p.F400L | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PLXDC1 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2
- PNMA8A | c.1210G>T p.A404S | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- PNPLA4 | c.32G>T p.C11F | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- PRPF3 | c.1517A>T p.K506I | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- PSMD6 | c.899G>C p.R300T | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RAB11FIP1 | c.95C>A p.A32D | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RAB2A | c.568C>G p.Q190E | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- RALGAPA1 | c.1546A>T p.T516S | Missense Mutation (SNP) | VAF 54/622 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- RANBP17 | c.3110A>T p.Q1037L | Missense Mutation (SNP) | VAF 51/282 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RANBP2 | c.5915C>G p.S1972* | Nonsense Mutation (SNP) | VAF 90/1071 reads (8%) | called by muse, mutect2
- RBM28 | c.1017C>T p.I339= | Splice Region (SNP) | VAF 26/572 reads (5%) | called by muse, mutect2
- RBM44 | c.229G>A p.E77K (on ENST00000611254; = p.E711K on NM_001080504.2) | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- RBM46 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBPMS | c.562C>G p.Q188E | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.585); called by muse, mutect2
- REG1B | c.322-1G>T p.X108_splice | Splice Site (SNP) | VAF 20/98 reads (20%) | called by muse, mutect2
- RFWD3 | c.391del p.H131Mfs*7 | Frame Shift Del (DEL) | VAF 44/298 reads (15%) | called by mutect2, pindel, varscan2
- RNMT | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 23/216 reads (11%) | called by muse, mutect2, varscan2
- RP1 | c.1121A>G p.E374G | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2
- RPGRIP1L | c.1822G>C p.E608Q | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RPS6KA4 | c.2132G>T p.R711L | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RSPH6A | c.1768C>G p.P590A | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, varscan2
- SAMD11 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2
- SCFD1 | c.1671G>A p.M557I | Missense Mutation (SNP) | VAF 15/410 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2
- SCLY | c.913G>C p.E305Q (on ENST00000651534; = p.E297Q on NM_016510.7) | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SEC24B | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SEZ6L | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 45/164 reads (27%) | called by muse, mutect2, varscan2
- SHROOM1 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- SLAMF6 | c.139G>T p.G47* | Nonsense Mutation (SNP) | VAF 16/260 reads (6%) | called by muse, mutect2
- SLC22A7 | c.584_599del p.Y195Sfs*17 (on ENST00000372585 / NM_153320.2; = p.Y193Sfs*17 on NM_006672.3) | Frame Shift Del (DEL) | VAF 34/323 reads (11%) | called by mutect2, pindel
- SLFN11 | c.1978G>T p.E660* | Nonsense Mutation (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- SLX4 | c.3722G>T p.R1241L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SNTG2 | c.633G>C p.R211S | Missense Mutation (SNP) | VAF 36/323 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SOWAHC | c.1343G>T p.W448L | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- SP140 | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 33/194 reads (17%) | called by muse, mutect2, varscan2
- SPHKAP | c.4449T>C p.S1483= | Splice Region (SNP) | VAF 6/42 reads (14%) | called by muse, varscan2
- SRFBP1 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- SSTR1 | c.838T>A p.F280I | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ST6GAL2 | c.431C>A p.T144N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- STK31 | c.2343G>C p.W781C | Missense Mutation (SNP) | VAF 10/323 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.029); called by muse, mutect2
- SUOX | c.303G>T p.W101C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE1 | c.10636C>T p.Q3546* (on ENST00000367255 / NM_182961.4; = p.Q3553* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 23/223 reads (10%) | called by muse, mutect2, varscan2
- TEAD4 | c.1215G>T p.Q405H | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- THAP4 | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR7 | c.3016A>T p.R1006W | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM233 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 20/281 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.218); called by muse, mutect2
- TRGV3 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 67/627 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- TRIM51 | c.572A>T p.H191L | Missense Mutation (SNP) | VAF 64/506 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TRPC4 | c.502G>T p.V168L | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- TRPM2 | c.2828T>C p.V943A | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); called by muse, varscan2
- TTI2 | c.1363C>G p.L455V | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- TUBB8 | c.824G>T p.S275I | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- UBR1 | c.2788C>G p.Q930E | Missense Mutation (SNP) | VAF 13/283 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- UBR5 | c.5774dup p.M1925Ifs*5 | Frame Shift Ins (INS) | VAF 45/332 reads (14%) | called by mutect2, pindel, varscan2
- UGT2B4 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- USP24 | c.7790A>G p.H2597R | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- USP28 | c.838C>G p.P280A | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- VARS2 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 20/119 reads (17%) | called by muse, mutect2, varscan2
- VCX | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- WDR12 | c.7C>G p.Q3E | Missense Mutation (SNP) | VAF 15/348 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.19); called by muse, mutect2
- WEE2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- WFS1 | c.811G>C p.D271H | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- YTHDC1 | c.1722A>T p.R574S (on ENST00000344157 / NM_001031732.4; = p.R556S on NM_133370.4) | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2
- ZC3HC1 | c.1279G>C p.D427H | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZDBF2 | c.4660C>A p.Q1554K | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.121); called by muse, mutect2
- ZFHX4 | c.4352T>A p.L1451Q | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ZMAT4 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF132 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZNF217 | c.317G>T p.S106I | Missense Mutation (SNP) | VAF 7/199 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.26); called by muse, mutect2
- ZNF513 | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2
- ZNF607 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2
- ZNF649 | c.1306G>C p.E436Q | Missense Mutation (SNP) | VAF 14/225 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.106); called by muse, mutect2
- ZNF669 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.327); called by muse, mutect2
- ADAMTS3 | c.2964G>A p.V988= | Silent (SNP) | VAF 14/298 reads (5%) | called by muse, mutect2
- AHCYL2 | c.219C>T p.L73= | Silent (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- AMER1 | c.205C>T p.L69= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- ANKH | c.309G>A p.L103= | Silent (SNP) | VAF 22/642 reads (3%) | called by muse, mutect2
- ANKRD53 | c.1056C>T p.S352= | Silent (SNP) | VAF 18/357 reads (5%) | called by muse, mutect2
- ASB15 | c.996T>C p.F332= | Silent (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- B2M | c.30C>T p.L10= | Silent (SNP) | VAF 20/574 reads (3%) | catalogued as COSV62563463; called by muse, mutect2
- C1orf167 | c.3219G>T p.G1073= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- C6 | c.1143T>C p.F381= | Silent (SNP) | VAF 41/169 reads (24%) | called by muse, mutect2, varscan2
- CCDC125 | c.960C>T p.Y320= | Silent (SNP) | VAF 35/156 reads (22%) | catalogued as rs757530927, COSV101143421; called by muse, mutect2, varscan2
- CCDC18 | c.3531C>T p.L1177= (on ENST00000343253 / NM_001306076.1; = p.L1178= on NM_206886.4) | Silent (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- CCDC97 | c.360G>T p.L120= | Silent (SNP) | VAF 17/125 reads (14%) | called by muse, mutect2, varscan2
- CD96 | c.624C>T p.S208= (on ENST00000283285 / NM_198196.3; = p.S192= on NM_005816.5) | Silent (SNP) | VAF 42/302 reads (14%) | called by muse, mutect2, varscan2
- CDH4 | c.960C>A p.T320= | Silent (SNP) | VAF 24/288 reads (8%) | called by muse, mutect2
- CNTNAP4 | c.3777C>T p.A1259= | Silent (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2
- CTAGE15 | c.1269C>A p.L423= | Silent (SNP) | VAF 78/320 reads (24%) | called by muse, mutect2, varscan2
- DOCK2 | c.5067C>A p.T1689= | Silent (SNP) | VAF 12/271 reads (4%) | called by muse, mutect2
- DOCK4 | c.5625C>T p.P1875= | Silent (SNP) | VAF 54/243 reads (22%) | catalogued as COSV101447953; called by muse, mutect2, varscan2
- EGFR | c.2370G>T p.T790= | Silent (SNP) | VAF 41/343 reads (12%) | called by muse, mutect2
- ESPN | c.513C>T p.N171= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as rs1016290026; called by muse, mutect2, varscan2
- FAM86B2 | c.678G>T p.L226= | Silent (SNP) | VAF 26/256 reads (10%) | catalogued as rs1351806292; called by mutect2, varscan2
- FBXO41 | c.2131A>C p.R711= | Silent (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
- GGN | c.1152T>C p.S384= | Silent (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- GIMAP1 | c.204G>C p.T68= | Silent (SNP) | VAF 14/184 reads (8%) | catalogued as rs946354751; called by muse, mutect2
- GRM5 | c.177G>T p.A59= | Silent (SNP) | VAF 75/518 reads (14%) | called by muse, mutect2, varscan2
- HAPLN2 | c.600C>T p.L200= | Silent (SNP) | VAF 14/272 reads (5%) | catalogued as COSV54815292; called by muse, mutect2
- ICE1 | c.5571A>G p.P1857= | Silent (SNP) | VAF 50/201 reads (25%) | catalogued as rs1373514211; called by muse, mutect2, varscan2
- IFNAR2 | c.1131C>T p.L377= | Silent (SNP) | VAF 33/323 reads (10%) | catalogued as rs1297320958; called by muse, mutect2, varscan2
- IL1R2 | c.594C>T p.A198= | Silent (SNP) | VAF 57/412 reads (14%) | catalogued as rs1165238372; called by muse, mutect2, varscan2
- IMPG2 | c.912C>T p.G304= | Silent (SNP) | VAF 40/244 reads (16%) | catalogued as rs780679713; called by muse, mutect2, varscan2
- ITCH | c.624C>T p.S208= (on ENST00000262650 / NM_001257137.3; = p.S167= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/468 reads (4%) | catalogued as rs977126637; called by muse, mutect2
- ITPR2 | c.1080C>T p.G360= | Silent (SNP) | VAF 33/245 reads (13%) | catalogued as rs1565692572; called by muse, mutect2, varscan2
- KDM5C | c.2013C>T p.F671= | Silent (SNP) | VAF 22/166 reads (13%) | catalogued as rs781858052; called by muse, mutect2, varscan2
- KLLN | c.75A>G p.K25= | Silent (SNP) | VAF 17/200 reads (9%) | catalogued as rs767531763; called by muse, mutect2
- KMO | c.768C>T p.F256= | Silent (SNP) | VAF 33/297 reads (11%) | called by muse, mutect2, varscan2
- LAMC1 | c.804A>G p.K268= | Silent (SNP) | VAF 39/287 reads (14%) | called by muse, mutect2, varscan2
- LCT | c.4155A>T p.A1385= | Silent (SNP) | VAF 10/306 reads (3%) | called by muse, mutect2
- LRP1B | c.12039G>A p.L4013= | Silent (SNP) | VAF 24/655 reads (4%) | called by muse, mutect2
- LVRN | c.1227C>A p.I409= | Silent (SNP) | VAF 51/339 reads (15%) | called by muse, mutect2, varscan2
- LZTS1 | c.1320G>T p.L440= | Silent (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- MMP27 | c.1464G>A p.K488= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as COSV52779831, COSV52782270, COSV52782352; called by muse, mutect2, varscan2
- MSH6 | c.1548C>T p.I516= | Silent (SNP) | VAF 15/392 reads (4%) | catalogued as COSV52286871; called by muse, mutect2
- MUC22 | c.4467C>T p.F1489= | Silent (SNP) | VAF 15/215 reads (7%) | catalogued as rs1211503501; called by muse, mutect2
- NKAIN3 | c.33C>T p.I11= | Silent (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- NOXO1 | c.357G>A p.T119= (on ENST00000397280 / NM_172168.3; = p.T113= on NM_144603.4) | Silent (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- NPAS3 | c.43C>A p.R15= | Silent (SNP) | VAF 126/316 reads (40%) | catalogued as rs1178666473, COSV100385944; called by muse, mutect2, varscan2
- OR2H2 | c.537C>A p.V179= | Silent (SNP) | VAF 37/169 reads (22%) | called by muse, mutect2, varscan2
- OR4C13 | c.399C>A p.V133= | Silent (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- OR52N1 | c.768A>T p.P256= | Silent (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- OR5W2 | c.432C>A p.L144= | Silent (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- OSBPL10 | c.1155G>A p.K385= | Silent (SNP) | VAF 24/221 reads (11%) | called by muse, mutect2, varscan2
- PAK3 | c.888T>A p.T296= (on ENST00000262836 / NM_001324328.2; = p.T281= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 19/174 reads (11%) | called by muse, mutect2
- PBX4 | c.759C>T p.T253= | Silent (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2
- PCNX1 | c.6267C>G p.L2089= | Silent (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- PIGC | c.63A>G p.R21= | Silent (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- PIGG | c.708G>C p.L236= | Silent (SNP) | VAF 15/207 reads (7%) | called by muse, mutect2
- PLOD1 | c.321A>G p.A107= | Silent (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- PLOD1 | c.1230G>A p.R410= | Silent (SNP) | VAF 29/325 reads (9%) | called by muse, mutect2
- PPP1R15A | c.108G>C p.L36= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- PTGDS | c.144C>T p.L48= | Silent (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- RASA1 | c.528T>A p.P176= | Silent (SNP) | VAF 15/382 reads (4%) | called by muse, mutect2
- RGS11 | c.744T>C p.L248= (on ENST00000397770 / NM_183337.3; = p.L227= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/179 reads (10%) | called by muse, mutect2
- RPGRIP1L | c.2025G>A p.K675= | Silent (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- RYR2 | c.1257C>A p.I419= | Silent (SNP) | VAF 21/324 reads (6%) | called by muse, mutect2
- SHROOM1 | c.2364C>G p.V788= (on ENST00000378679 / NM_001172700.2; = p.V783= on NM_133456.2) | Silent (SNP) | VAF 34/188 reads (18%) | catalogued as rs765300774; called by muse, mutect2, varscan2
- SLC35F3 | c.1077C>A p.V359= (on ENST00000366617 / NM_001300845.1; = p.V428= on NM_173508.4) | Silent (SNP) | VAF 53/358 reads (15%) | called by muse, mutect2, varscan2
- SMAD1 | c.1281G>A p.Q427= | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as rs753995334, COSV57470517; called by muse, mutect2
- SPINDOC | c.24C>T p.A8= | Silent (SNP) | VAF 9/161 reads (6%) | called by muse, mutect2
- SPTBN5 | c.6423G>T p.R2141= | Silent (SNP) | VAF 19/161 reads (12%) | called by muse, mutect2, varscan2
- TBC1D32 | c.177C>T p.L59= | Silent (SNP) | VAF 7/117 reads (6%) | catalogued as COSV51537839; called by muse, mutect2
- TCHHL1 | c.123T>C p.F41= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV64284922; called by muse, mutect2, varscan2
- TCL1B | c.126G>T p.S42= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs563494390, COSV61551921; called by muse, mutect2, varscan2
- TDRP | c.240G>A p.L80= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- TIPARP | c.1863T>C p.S621= | Silent (SNP) | VAF 42/332 reads (13%) | called by muse, mutect2, varscan2
- TMEM131 | c.1950G>A p.Q650= | Silent (SNP) | VAF 32/196 reads (16%) | called by muse, mutect2, varscan2
- TMEM200C | c.759C>T p.Y253= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as rs957925838; called by muse, mutect2
- TRPM2 | c.2568G>A p.L856= | Silent (SNP) | VAF 8/194 reads (4%) | called by muse, mutect2
- TSPYL6 | c.1030C>A p.R344= | Silent (SNP) | VAF 18/155 reads (12%) | called by muse, varscan2
- ZCCHC2 | c.606C>G p.L202= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- ZNF132 | c.918G>A p.L306= | Silent (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- ZNF354C | c.1086G>A p.G362= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as COSV100203738; called by muse, mutect2
- ZNF534 | c.564A>G p.Q188= (on ENST00000332323 / NM_001143939.3; = p.Q175= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/155 reads (11%) | catalogued as rs1445767658, COSV56516065; called by muse, mutect2, varscan2
- ZNF729 | c.3180C>A p.S1060= | Silent (SNP) | VAF 30/341 reads (9%) | catalogued as rs1365025881, COSV62604119; called by muse, mutect2
- ZNF836 | c.2451G>A p.V817= | Silent (SNP) | VAF 20/262 reads (8%) | catalogued as rs1431716594; called by muse, mutect2
- ABCG1 | c.-1G>C | 5'UTR (SNP) | VAF 11/255 reads (4%) | called by muse, mutect2
- ACTR6 | c.68+12C>G | Intron (SNP) | VAF 22/206 reads (11%) | catalogued as COSV99498811; called by muse, mutect2
- ADAR | c.-10C>T | 5'UTR (SNP) | VAF 21/358 reads (6%) | catalogued as COSV52722231; called by muse, mutect2
- ALG2 | c.*1402C>T | 3'UTR (SNP) | VAF 7/133 reads (5%) | catalogued as rs1366146140; called by muse, mutect2
- AP000769.3 | chr11:65506389 A>G | 3'Flank (SNP) | VAF 4/15 reads (27%) | catalogued as rs545880461; called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916166 G>T | 5'Flank (SNP) | VAF 24/113 reads (21%) | called by muse, mutect2, varscan2
- BIRC3 | c.953+1198del | Intron (DEL) | VAF 56/417 reads (13%) | called by mutect2, pindel, varscan2
- BLK | c.1029+876A>T | Intron (SNP) | VAF 15/200 reads (8%) | called by muse, mutect2
- CALM2 | c.3+11C>T | Intron (SNP) | VAF 10/162 reads (6%) | catalogued as rs1215227580; called by muse, mutect2
- CPT2 | c.-29C>T | 5'UTR (SNP) | VAF 13/256 reads (5%) | catalogued as rs1256996218; called by muse, mutect2
- CRIM1 | c.332-18203G>T | Intron (SNP) | VAF 31/228 reads (14%) | called by muse, mutect2, varscan2
- CSRP2 | c.505+54G>C | Intron (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2
- CYB5A | c.289-1040T>G | Intron (SNP) | VAF 93/401 reads (23%) | called by muse, mutect2, varscan2
- CYB5RL | c.541-668G>T | Intron (SNP) | VAF 48/161 reads (30%) | catalogued as rs750882283; called by muse, mutect2, varscan2
- CYP2B7P | n.252C>T | RNA (SNP) | VAF 20/384 reads (5%) | called by muse, mutect2
- DNM1P46 | n.421C>A | RNA (SNP) | VAF 43/199 reads (22%) | called by muse, mutect2, varscan2
- EPC2 | c.313+1450G>T | Intron (SNP) | VAF 34/175 reads (19%) | called by muse, mutect2, varscan2
- FAM90A20P | n.984G>A | RNA (SNP) | VAF 36/633 reads (6%) | catalogued as rs750628130; called by muse, mutect2
- FOLR2 | c.-80G>A | 5'UTR (SNP) | VAF 14/110 reads (13%) | catalogued as rs756551102; called by muse, varscan2
- GSE1 | c.-29C>T | 5'UTR (SNP) | VAF 19/213 reads (9%) | catalogued as rs766811967; called by muse, mutect2
- HECTD4 | c.12047-53G>T | Intron (SNP) | VAF 49/147 reads (33%) | catalogued as rs1481166619; called by muse, mutect2, varscan2
- ITGA3 | c.*170C>T | 3'UTR (SNP) | VAF 34/146 reads (23%) | catalogued as rs753479348; called by muse, mutect2, varscan2
- ITPA | c.411+30C>T | Intron (SNP) | VAF 44/184 reads (24%) | called by muse, mutect2, varscan2
- KCNN1 | c.*1559C>A | 3'UTR (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2, varscan2
- KCNU1 | c.2010-16880G>T | Intron (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- KEL | c.1315-32T>C | Intron (SNP) | VAF 28/294 reads (10%) | called by muse, mutect2
- KLHL13 | c.-524C>T | 5'UTR (SNP) | VAF 31/143 reads (22%) | called by muse, mutect2, varscan2
- LINC02054 | n.2370C>G | RNA (SNP) | VAF 12/235 reads (5%) | called by muse, mutect2
- LINC02210-CRHR1 | c.-493+11412C>G | Intron (SNP) | VAF 12/290 reads (4%) | called by muse, mutect2
- MACF1 | c.543+10824C>T | Intron (SNP) | VAF 9/160 reads (6%) | called by muse, mutect2
- MAG | chr19:35292154 G>T | 5'Flank (SNP) | VAF 14/236 reads (6%) | called by muse, mutect2
- MAP3K19 | c.22+1091A>G | Intron (SNP) | VAF 42/247 reads (17%) | called by muse, mutect2, varscan2
- MYH2 | c.204+44T>A | Intron (SNP) | VAF 77/434 reads (18%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1580G>T | RNA (SNP) | VAF 44/296 reads (15%) | called by muse, mutect2, varscan2
- NUP214 | c.*52C>G | 3'UTR (SNP) | VAF 20/318 reads (6%) | called by muse, mutect2
- OR10V2P | n.259C>A | RNA (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- ORC5 | c.-5C>G | 5'UTR (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- PCDHGA3 | c.2425-66782G>C | Intron (SNP) | VAF 13/192 reads (7%) | catalogued as COSV52759371; called by muse, mutect2
- PILRB | c.-145A>C | 5'UTR (SNP) | VAF 35/279 reads (13%) | catalogued as rs1474354767; called by muse, mutect2, varscan2
- PLCZ1 | c.12-379C>A | Intron (SNP) | VAF 20/222 reads (9%) | called by muse, mutect2
- PLS3 | c.892-292G>C | Intron (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- PRKCG | c.*11C>T | 3'UTR (SNP) | VAF 37/102 reads (36%) | catalogued as rs1271982202; called by muse, mutect2, varscan2
- PRSS30P | n.1338G>T | RNA (SNP) | VAF 25/163 reads (15%) | called by muse, mutect2, varscan2
- PUM1 | c.-29C>A | 5'UTR (SNP) | VAF 16/206 reads (8%) | catalogued as rs1299211408; called by muse, mutect2
- RSPO3 | c.*1474C>A | 3'UTR (SNP) | VAF 39/287 reads (14%) | called by muse, mutect2, varscan2
- SCN2A | c.*47G>T | 3'UTR (SNP) | VAF 19/102 reads (19%) | catalogued as rs377384458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SFXN5 | c.945+4146G>T | Intron (SNP) | VAF 36/119 reads (30%) | called by muse, mutect2, varscan2
- SLC13A2 | c.232-83C>A | Intron (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- SLC3A2 | chr11:62853928 C>A | 5'Flank (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- SLC6A10P | n.2955C>T | RNA (SNP) | VAF 17/306 reads (6%) | called by muse, mutect2
- SNX13 | c.-115G>A | 5'UTR (SNP) | VAF 10/267 reads (4%) | called by muse, mutect2
- SPATA31C2 | n.3467G>T | RNA (SNP) | VAF 99/534 reads (19%) | called by muse, mutect2, varscan2
- SSPOP | n.4248G>A | RNA (SNP) | VAF 22/80 reads (28%) | catalogued as rs763049277, COSV100022257; called by muse, mutect2
- SSPOP | n.10585G>T | RNA (SNP) | VAF 40/251 reads (16%) | called by muse, mutect2, varscan2
- SUGCT | c.100+6750A>G | Intron (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- SVIL2P | n.1805A>C | RNA (SNP) | VAF 35/248 reads (14%) | called by muse, mutect2, varscan2
- TFAP2A | c.486+99C>A | Intron (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- THUMPD2 | c.892-1398G>T | Intron (SNP) | VAF 23/218 reads (11%) | catalogued as rs549569259; called by muse, varscan2
- TPRXL | n.1080G>T | RNA (SNP) | VAF 31/210 reads (15%) | called by muse, varscan2
- TTN | c.34265-3041G>A | Intron (SNP) | VAF 51/332 reads (15%) | called by muse, mutect2, varscan2
- UQCRB | c.*369G>A | 3'UTR (SNP) | VAF 50/435 reads (11%) | called by muse, mutect2, varscan2
- XIST | n.9855G>T | RNA (SNP) | VAF 51/199 reads (26%) | called by muse, mutect2, varscan2
- Y_RNA | chr7:23491067 C>A | 3'Flank (SNP) | VAF 30/221 reads (14%) | called by muse, mutect2, varscan2
- ZIC3 | c.*33G>A | 3'UTR (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- ZNF252P | n.479G>T | RNA (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2, varscan2
- ZNF511 | c.*842C>T | 3'UTR (SNP) | VAF 26/141 reads (18%) | catalogued as rs1195704777; called by muse, mutect2, varscan2
- ZNF74 | c.121-1041A>T | Intron (SNP) | VAF 20/84 reads (24%) | catalogued as rs1163647059; called by muse, mutect2, varscan2
- ZNF783 | c.-46C>G | 5'UTR (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- ZNF971P | n.1003C>T | RNA (SNP) | VAF 28/576 reads (5%) | called by muse, mutect2
